Somatic mutation profile of tumor specimen TCGA-FP-8631-01A (aliquot TCGA-FP-8631-01A-11D-2394-08) from TCGA case TCGA-FP-8631, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.2 years (24,898 days).
Specimen TCGA-FP-8631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d1ae48d-dcd1-4035-835b-b85c4d2b2a53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-8631-10A (Blood Derived Normal), aliquot TCGA-FP-8631-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d19b956e-0712-46d8-bc1d-a2cc4c725886

The open-access MAF lists 109 somatic variants for this specimen: 76 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 29, Nonsense Mutation 7, Frame Shift Del 3, 3'Flank 2, Intron 2, Frame Shift Ins 2, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 66/99 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANAPC5 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV99946059; called by muse, mutect2, varscan2
- ANO3 | c.2613C>A p.F871L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV56811628; called by muse, mutect2, varscan2
- CACNA1E | c.3977A>G p.E1326G | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV62434986; called by muse, mutect2, varscan2
- CD101 | c.2136T>G p.I712M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV56721750; called by muse, mutect2, varscan2
- CDH8 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV54851239; called by muse, mutect2, varscan2
- CDH8 | c.1177T>C p.S393P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as COSV100180536; called by muse, mutect2, varscan2
- CENPE | c.4394T>C p.I1465T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV54392303; called by muse, mutect2, varscan2
- CHD6 | c.6489G>C p.E2163D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64695416; called by muse, mutect2
- CMAS | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs978646578, COSV57556693; called by muse, mutect2, varscan2
- CNGA4 | c.1643C>G p.A548G | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.125); catalogued as rs752306802, COSV66007226; called by muse, mutect2, varscan2
- COL22A1 | c.1237C>G p.P413A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100277324; called by muse, varscan2
- COL4A4 | c.2930C>T p.P977L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV61637345; called by muse, mutect2, varscan2
- COLEC12 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV101232017; called by muse, mutect2, varscan2
- DNAH11 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as rs1226560314, COSV60986297; called by muse, mutect2, varscan2
- EDN3 | c.610A>G p.S204G (on ENST00000337938 / NM_001302455.2; = p.K215= on NM_207032.3) | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV61110668; called by muse, mutect2, varscan2
- EIF2AK3 | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as COSV57552936; called by muse, mutect2, varscan2
- EPRS1 | c.325A>G p.R109G | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV65101980; called by muse, mutect2, varscan2
- EVI2B | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV58364216, COSV58365301; called by muse, mutect2, varscan2
- FABP12 | c.166A>T p.S56C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64617425, COSV64617928; called by muse, mutect2, varscan2
- FBLIM1 | c.667T>A p.F223I | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60032028; called by muse, mutect2, varscan2
- FBN1 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.422); catalogued as COSV57332721; called by muse, mutect2
- FCRLA | c.410G>A p.R137Q (on ENST00000367959; = p.R114Q on NM_032738.4) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.298); catalogued as rs145034072, COSV52684449; called by muse, mutect2, varscan2
- FGD2 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51466465; called by muse, mutect2, varscan2
- FYTTD1 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV54086839; called by muse, mutect2, varscan2
- GLI3 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV101229788; called by muse, mutect2, varscan2
- GPC6 | c.1442A>T p.N481I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV65542040; called by muse, mutect2, varscan2
- IFITM2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100068210; called by muse, mutect2, varscan2
- ITPR2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67277338; called by muse, mutect2, varscan2
- KNTC1 | c.3435A>C p.P1145= | Splice Region (SNP) | VAF 24/50 reads (48%) | catalogued as COSV61085201; called by muse, mutect2, varscan2
- LRRK1 | c.2318C>T p.T773M | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.401); catalogued as rs377308921; called by muse, mutect2, varscan2
- MADD | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100211248; called by muse, mutect2, varscan2
- MARCHF1 | c.559G>A p.G187S (on ENST00000274056; = p.G170S on NM_017923.4) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV56834551; called by muse, mutect2
- METTL2A | c.972C>G p.F324L | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61046447; called by muse, mutect2, varscan2
- MOXD1 | c.1394G>A p.C465Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60950142; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs765184193; called by pindel, varscan2
- MYLPF | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs375102609; called by muse, mutect2, varscan2
- MYO5A | c.2817G>A p.Q939= | Splice Region (SNP) | VAF 21/83 reads (25%) | catalogued as COSV62565614; called by muse, mutect2, varscan2
- MYOZ2 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as COSV61086477; called by muse, mutect2, varscan2
- NES | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 140/408 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV63963316; called by muse, mutect2, varscan2
- NLRP13 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs766502530, COSV61624424; called by muse, mutect2, varscan2
- NUDT7 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV51747411; called by muse, mutect2, varscan2
- OAS3 | c.1541G>A p.S514N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57449941; called by muse, mutect2, varscan2
- OR10AG1 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV56634957, COSV56635290; called by muse, mutect2, varscan2
- OR4A16 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV59045388; called by muse, mutect2, varscan2
- ORMDL2 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV54479520; called by muse, mutect2, varscan2
- PCDHA13 | c.1897A>T p.T633S | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV56553194; called by muse, mutect2, varscan2
- PCSK2 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99359134; called by muse, mutect2
- PLEC | c.6028G>A p.E2010K (on ENST00000322810 / NM_201380.4; = p.E1900K on NM_000445.5) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as rs367715409; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHA7 | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1256008057, COSV60580727, COSV60581089; called by muse, mutect2, varscan2
- PRDM9 | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV57010245, COSV99690126; called by muse, mutect2, varscan2
- PRDM9 | c.1011G>T p.R337S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV57008451, COSV99690128; called by muse, mutect2, varscan2
- PRPF8 | c.2572C>T p.Q858* | Nonsense Mutation (SNP) | VAF 38/94 reads (40%) | catalogued as COSV59260450, COSV59268601; called by muse, mutect2, varscan2
- RANBP2 | c.5501G>C p.G1834A | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51709881; called by muse, mutect2, varscan2
- RET | c.3134A>G p.N1045S | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as COSV60710665; called by muse, mutect2, varscan2
- RICTOR | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57122978, COSV57132039; called by muse, mutect2, varscan2
- SCN10A | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746092299, COSV71861958; called by muse, mutect2, varscan2
- SCN11A | c.3418T>G p.L1140V | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV56566210; called by muse, mutect2, varscan2
- SI | c.2715C>A p.F905L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761448340, COSV52304832; called by muse, mutect2, varscan2
- SLC6A9 | c.287A>G p.Q96R (on ENST00000360584 / NM_201649.4; = p.Q42R on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV62212392; called by muse, mutect2, varscan2
- SLC7A14 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs202048294, COSV51581905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYCP3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as COSV57150347; called by muse, mutect2, varscan2
- TARBP1 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV50211945; called by muse, mutect2, varscan2
- TBC1D31 | c.1638A>C p.E546D | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54871692; called by muse, mutect2, varscan2
- TMC2 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV62650556, COSV62659206; called by muse, mutect2, varscan2
- TP63 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.108); catalogued as COSV53223192; called by muse, mutect2, varscan2
- TRIOBP | c.4627G>C p.G1543R | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV60385568; called by muse, mutect2, varscan2
- TTF2 | c.3313G>A p.V1105I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65634003; called by muse, mutect2, varscan2
- TTN | c.81841G>T p.E27281* (on ENST00000591111; = p.E19857* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 32/160 reads (20%) | catalogued as COSV60039454, COSV60399477; called by muse, mutect2, varscan2
- TUSC3 | c.695C>A p.A232D | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65879038, COSV65887771; called by muse, mutect2, varscan2
- ARID1A | c.1513_1514del p.Q505Vfs*117 | Frame Shift Del (DEL) | VAF 127/505 reads (25%) | called by pindel, varscan2
- ECD | c.604dup p.I202Nfs*41 | Frame Shift Ins (INS) | VAF 16/159 reads (10%) | called by mutect2, pindel, varscan2
- ELP1 | c.3817del p.I1273Ffs*15 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- LCA5L | c.25del p.T9Qfs*3 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | called by pindel, varscan2
- PITX1 | c.435dup p.K146* | Frame Shift Ins (INS) | VAF 48/141 reads (34%) | called by mutect2, pindel, varscan2
- TUBB2B | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); called by mutect2, varscan2
- ADAR | c.393G>A p.Q131= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV52722313; called by muse, mutect2, varscan2
- AGPAT3 | c.714G>A p.P238= | Silent (SNP) | VAF 161/351 reads (46%) | catalogued as COSV52374598; called by muse, mutect2, varscan2
- ARSF | c.486C>T p.Y162= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs138766548, COSV63841288; called by muse, mutect2, varscan2
- CCN4 | c.957C>T p.D319= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs758449163, COSV51532842; called by muse, mutect2, varscan2
- CEP170B | c.3054G>A p.P1018= (on ENST00000453495; = p.P947= on NM_015005.3) | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs781246514, COSV69026989; called by muse, mutect2, varscan2
- COL7A1 | c.3735G>A p.E1245= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV60404328; called by muse, mutect2, varscan2
- FAT2 | c.1386C>A p.S462= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV55831428; called by muse, mutect2, varscan2
- GLI3 | c.417C>G p.A139= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV101229787; called by muse, mutect2, varscan2
- HEY2 | c.897G>A p.A299= | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as COSV64240380; called by muse, mutect2, varscan2
- HLA-G | c.165G>A p.T55= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV64407183; called by muse, mutect2, varscan2
- HMCN1 | c.9492G>A p.T3164= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs747523783, COSV54875799; called by muse, mutect2, varscan2
- HUWE1 | c.8580C>T p.S2860= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53366866; called by muse, mutect2, varscan2
- KCTD17 | c.546G>A p.E182= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as rs1275803205, COSV63249139; called by muse, varscan2
- MAGEB3 | c.888T>C p.N296= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV64397853; called by muse, mutect2, varscan2
- MED19 | c.276C>G p.A92= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV54709591; called by muse, mutect2, varscan2
- MED24 | c.1305G>T p.L435= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV62421558; called by muse, mutect2, varscan2
- MUC16 | c.21444A>G p.V7148= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV67500175; called by muse, mutect2
- NIPAL1 | c.735G>A p.L245= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV55007957; called by muse, mutect2, varscan2
- NPLOC4 | c.588G>A p.G196= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs1401456408, COSV58620502; called by muse, mutect2, varscan2
- OR2AK2 | c.255C>T p.F85= | Silent (SNP) | VAF 78/171 reads (46%) | catalogued as COSV63562838; called by muse, mutect2, varscan2
- OR4B1 | c.78T>C p.F26= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV58882228, COSV58884249; called by muse, mutect2, varscan2
- PPP1R12C | c.2148G>A p.E716= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs747042695, COSV52387157; called by muse, mutect2, varscan2
- SCARA5 | c.1413C>T p.R471= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV61574642; called by muse, mutect2, varscan2
- SCUBE1 | c.2853G>A p.A951= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs142852064; called by muse, mutect2, varscan2
- SIK2 | c.684G>A p.R228= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs201271483, COSV59250484, COSV59255850; called by muse, mutect2, varscan2
- SUSD1 | c.916C>T p.L306= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV62585734; called by muse, mutect2, varscan2
- THSD7A | c.1422C>T p.L474= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as rs532771649, COSV70274291; called by muse, mutect2, varscan2
- UNC5B | c.2094C>G p.A698= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV58982052; called by muse, mutect2, varscan2
- ZSCAN25 | c.1566C>T p.S522= | Silent (SNP) | VAF 46/77 reads (60%) | catalogued as rs768065140, COSV53554806; called by muse, mutect2, varscan2
- DISC1 | c.1117+20551C>T | Intron (SNP) | VAF 22/61 reads (36%) | catalogued as rs764879895, COSV54422271; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876127 G>C | 3'Flank (SNP) | VAF 12/100 reads (12%) | catalogued as rs1301495785; called by mutect2, varscan2
- OTOA | c.1023-134C>T | Intron (SNP) | VAF 49/313 reads (16%) | catalogued as COSV99624069; called by muse, mutect2, varscan2
- TRPV2 | chr17:16440183 A>G | 3'Flank (SNP) | VAF 15/45 reads (33%) | catalogued as rs112824075; called by muse, mutect2, varscan2
